Surgical pathology report (de-identified scan), TCGA case TCGA-77-8145, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8145-01A (Primary Tumor).

[page 1 of 3]
Collected [REDACTED]

Histopathology Report [REDACTED]

LEFT LUNG, LYMPH NODES AND PULMONARY VEIN STUMP

Clinical Notes:

[REDACTED] male with SCC left upper lobe bronchus.
? involvement of superior pulmonary vein into left atrium.
? free margin.

Five specimens are received:

1: LEFT LUNG

Macroscopy:

Specimen is labelled "left lung" and consists of a left lung measuring 255 x 180 x approximately 65 mm. There is approximately 28 mm of left main bronchus attached to the specimen. The pleural surface is puckered over the lower lateral aspect of the upper lobe. In addition there are bullae present at the apex of the upper lobe ranging in size from 3-20 mm. The pleural surface is also puckered on the medial surface of the upper lobe immediately anterior to the hilum. On sectioning through the lung parenchyma, there is a large lesion present, which arises from the left upper lobe bronchus approximately 50 mm from the bronchial resection margin. The lesion measures approximately 65 x 50 x 50 mm. The tumour lies immediately deep to the hilum but extends through the lung parenchyma to lie beneath the puckered pleural surface on the lateral aspect of the lung. The tumour appears to involve predominantly the upper lobe but also involves the upper portion of the lower lobe. There is an area of cavitation present within the tumour measuring approximately 25 mm in diameter. Tumour macroscopically involves the pulmonary vein and appears to come to within 1 mm of the resection margin of the specimen. Tumour appears to directly invade several parabrachial lymph nodes. The lesion appears to extend close to and has caused puckering of the overlying pleural surface. The tumour has a heterogeneous appearance on cut surface with firm cream areas and softer great black areas. [Sections taken through bronchial resection margin, A; hilar lymph nodes, B; pulmonary artery resection margin, C; pulmonary vein resection margin with underlying tumour, D and E; lateral pleural surface with underlying tumour and cavity formation, F and G; medial pleural surface with underlying tumour, H; further sections through tumour, I; medial pleural surface with underlying tumour, J; random sections through upper lobe, K and L; random section through lower lobe, M].

2: NUMBER SEVEN LYMPH NODE

Macroscopy:

Specimen is labelled "number seven lymph node" and consists of a single piece of tan solid tissue measuring 70 x 18 x 12 mm. On sectioning a large lymph

[page 2 of 3]
Collected [REDACTED]

Histopathology Report

node is apparent. [2TS, 2A and 2B].

3: NUMBER EIGHT LYMPH NODE

Macroscopy:

Specimen is labelled "number eight lymph node" and consists of a single piece of tan solid tissue measuring 14 x 10 x 5 mm. [Bisected and BIT, 3A].

4: NUMBER 10 LYMPH NODE

Macroscopy:

Specimen is labelled "number ten node" and consists of a single piece of tan solid tissue measuring 25 x 15 x 7 mm. [Bisected and BIT, 4A].

5: PULMONARY VEIN STUMP

Macroscopy:

Specimen is labelled "pulmonary vein stump" and consists of a single piece of fibrofatty tissue measuring 6 x 5 x 2 mm. [BIT, 5A]. [REDACTED]

Microscopy:

Specimens 1-5:

Sections show a moderately differentiated squamous cell carcinoma with extensive central necrosis. Tumour invades the overlying pleura on both the medial and lateral aspects of the upper lobe. Numerous foci of venous invasion are present, including involvement of the main pulmonary vein where tumour invades through the vein wall to lie just beneath the endothelium. Several foci of organising mural thrombus are present in the vein but the venous resection margin is clear of tumour. The section labelled "pulmonary vein stump" comprises a small portion of atrial wall in which there is no evidence of malignancy. The bronchial resection margin is clear of malignancy and shows no evidence of squamous metaplasia or dysplasia. Definite lymphatic invasion is not identified, however one of the hilar lymph nodes (no. 10, block 4A) shows metastatic carcinoma. The peribronchial lymph nodes and the other separately sampled lymph nodes show no evidence of malignancy. Lung parenchyma away from the tumour is confirmed to show severe emphysema, and the section from the lower lobe shows, in addition, numerous foci of ossification.

Conclusion:

Left pneumonectomy, lymph node sampling and pulmonary vein stump: Moderately differentiated squamous cell carcinoma, 65 mm in diameter, invading medial and lateral pleural surfaces and pulmonary vein; single hilar node metastasis; pathological stage T3 N1.

[page 3 of 3]
Collected

Histopathology Report

Addendum report:

Review of the sections of the pulmonary vein resection margin (blocks 1D and 1E) reveals atrial muscle invaded by tumour. The pathological stage should therefore be upgraded to T4 N1.

cc: Lung Cancer Registry
cc: Registrar, Thoracic Surgery

Source: NCI Genomic Data Commons file 60088a8f-9543-42fa-ac92-376fe0382b9c (TCGA-77-8145.E046EA53-A90C-4483-9398-BF3961AF868B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).